MMRF case MMRF_2577 — Multiple Myeloma CoMMpass Study (MMRF-COMMPASS)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Plasma Cell Tumors; Primary site: Hematopoietic and reticuloendothelial systems. Index date (day 0 for every day count below): first treatment.
https://portal.gdc.cancer.gov/cases/83bcfb26-63a3-4837-b4dd-3ba8a3aab8a4

Demographics
Sex at birth: male; Race: white; Ethnicity: not hispanic or latino; Age at index: 51 years; Vital status: Alive.

Diagnoses (1)
1. Multiple myeloma: ICD-O-3 morphology code: 9732/3; Tissue or organ of origin: Bone marrow; Site of resection or biopsy: Bone marrow; Age at diagnosis: 51.3 years (18,753 days); ISS stage: II; Days to last known disease status: 605 days (1.7 years); Days to last follow up: 605 days (1.7 years).
   Treatment given: Therapeutic agents: Bortezomib; Regimen or line of therapy: First line of therapy; Days to treatment start: 1 day; Days to treatment end: 191 days.
   Treatment given: Therapeutic agents: Cyclophosphamide; Regimen or line of therapy: First line of therapy; Days to treatment start: 1 day; Days to treatment end: 171 days.
   Treatment given: Therapeutic agents: Dexamethasone; Regimen or line of therapy: First line of therapy; Days to treatment start: 1 day.
   Treatment given: Therapeutic agents: Lenalidomide; Regimen or line of therapy: First line of therapy; Days to treatment start: 171 days.
   Treatment given: Therapeutic agents: Ixazomib; Regimen or line of therapy: First line of therapy; Days to treatment start: 185 days.

Molecular and laboratory tests (laboratory values one line per visit day; values rounded to 3 significant figures where GDC's unit conversion carried more)
- Day -18 (ECOG 1): M Protein 5.49 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 99.1 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.06 mg/dL; Immunoglobulin G 79.9 g/L; Immunoglobulin A 0.2 g/L; Immunoglobulin M 0.13 g/L; Beta 2 Microglobulin 4.29 µg/mL; Lactate Dehydrogenase 5.12 µkat/L; Hemoglobin 5.64 mmol/L; Leukocytes 4.4 ×10⁹/L; Absolute Neutrophil 1.9 ×10⁹/L; Platelets 164 ×10⁹/L; Creatinine 91.9 µmol/L; Blood Urea Nitrogen 6.07 mmol/L; Calcium 2.4 mmol/L; Albumin 41 g/L; Total Protein 11.7 g/dL; Glucose 7.21 mmol/L.
- Day 80 (ECOG 1): M Protein 1.16 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 12.7 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.082 mg/dL; Immunoglobulin G 15.3 g/L; Immunoglobulin A 0.12 g/L; Immunoglobulin M 0.21 g/L; Lactate Dehydrogenase 5.38 µkat/L; Hemoglobin 6.7 mmol/L; Leukocytes 4.7 ×10⁹/L; Absolute Neutrophil 3.4 ×10⁹/L; Platelets 175 ×10⁹/L; Creatinine 53.9 µmol/L; Blood Urea Nitrogen 3.93 mmol/L; Calcium 2.08 mmol/L; Albumin 38 g/L; Total Protein 6.7 g/dL; Glucose 8.64 mmol/L.
- Day 171 (ECOG 1): M Protein 0.63 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 6.08 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.34 mg/dL; Immunoglobulin G 10.9 g/L; Immunoglobulin A 1.13 g/L; Immunoglobulin M 0.97 g/L; Lactate Dehydrogenase 4.93 µkat/L; Hemoglobin 7.19 mmol/L; Leukocytes 4.3 ×10⁹/L; Absolute Neutrophil 2.4 ×10⁹/L; Platelets 214 ×10⁹/L; Creatinine 66.3 µmol/L; Blood Urea Nitrogen 3.93 mmol/L; Calcium 2.13 mmol/L; Albumin 38 g/L; Total Protein 6.7 g/dL; Glucose 6.82 mmol/L.
- Day 247 (ECOG 1): M Protein 0.37 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 3.74 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.951 mg/dL; Immunoglobulin G 7.15 g/L; Immunoglobulin A 0.72 g/L; Immunoglobulin M 0.67 g/L; Lactate Dehydrogenase 4.6 µkat/L; Hemoglobin 8.25 mmol/L; Leukocytes 4.3 ×10⁹/L; Absolute Neutrophil 2.5 ×10⁹/L; Platelets 182 ×10⁹/L; Creatinine 58.3 µmol/L; Blood Urea Nitrogen 4.28 mmol/L; Calcium 2.15 mmol/L; Albumin 43 g/L; Total Protein 6.7 g/dL; Glucose 7.15 mmol/L.
- Day 331 (ECOG 1): M Protein 0.39 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 2.74 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.244 mg/dL; Immunoglobulin G 8.19 g/L; Immunoglobulin A 0.81 g/L; Immunoglobulin M 0.58 g/L; Lactate Dehydrogenase 3.92 µkat/L; Hemoglobin 8.12 mmol/L; Leukocytes 6 ×10⁹/L; Absolute Neutrophil 3.8 ×10⁹/L; Platelets 147 ×10⁹/L; Creatinine 58.3 µmol/L; Blood Urea Nitrogen 5.36 mmol/L; Calcium 2.08 mmol/L; Albumin 40 g/L; Total Protein 6.2 g/dL; Glucose 7.21 mmol/L.
- Day 437 (ECOG 1): M Protein 0.31 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 3.55 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.681 mg/dL; Immunoglobulin G 7.18 g/L; Immunoglobulin A 0.71 g/L; Immunoglobulin M 0.74 g/L; Lactate Dehydrogenase 3.13 µkat/L; Hemoglobin 8 mmol/L; Leukocytes 5.8 ×10⁹/L; Absolute Neutrophil 4.4 ×10⁹/L; Platelets 120 ×10⁹/L; Creatinine 69.8 µmol/L; Blood Urea Nitrogen 5 mmol/L; Calcium 2.28 mmol/L; Albumin 41 g/L; Total Protein 5.7 g/dL; Glucose 5.34 mmol/L.
- Day 521 (ECOG 0): M Protein 0.2 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.46 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.701 mg/dL; Immunoglobulin G 4.46 g/L; Immunoglobulin A 0.44 g/L; Immunoglobulin M 0.81 g/L; Lactate Dehydrogenase 4.15 µkat/L; Hemoglobin 7.81 mmol/L; Leukocytes 3.3 ×10⁹/L; Absolute Neutrophil 2.4 ×10⁹/L; Platelets 91 ×10⁹/L; Creatinine 60.1 µmol/L; Blood Urea Nitrogen 3.57 mmol/L; Calcium 2.08 mmol/L; Albumin 39 g/L; Total Protein 5.9 g/dL; Glucose 9.46 mmol/L.
- Day 605 (ECOG 0): M Protein 0.19 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.8 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.45 mg/dL; Immunoglobulin G 4.26 g/L; Immunoglobulin A 4.69 g/L; Immunoglobulin M 0.25 g/L; Lactate Dehydrogenase 3.52 µkat/L; Hemoglobin 7.69 mmol/L; Leukocytes 4.7 ×10⁹/L; Absolute Neutrophil 3.3 ×10⁹/L; Platelets 117 ×10⁹/L; Creatinine 59.2 µmol/L; Blood Urea Nitrogen 3.21 mmol/L; Calcium 2.18 mmol/L; Albumin 38 g/L; Total Protein 4.9 g/dL; Glucose 9.79 mmol/L.

Other clinical attributes
- Day -18: Weight: 127 kg; Height: 175 cm.

Biospecimens (2 samples)
- Sample MMRF_2577_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS; Days to sample procurement: -18 days.
- Sample MMRF_2577_1_PB_Whole: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS; Days to sample procurement: -18 days.
